Gene-level copy-number profile of tumor specimen TCGA-69-7763-01A from TCGA case TCGA-69-7763, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 69.3 years (25,316 days).
Specimen TCGA-69-7763-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUAD.f0a12b4f-d5b0-4b27-a918-8290391755d1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-69-7763-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1abf4e04-2085-4b15-8860-57220fd2defe

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 4,724; copy number 2: 28,984; copy number 3: 17,787; copy number 4: 8,160; copy number 5: 130; copy number 6: 9; copy number 8: 26.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-69-7763-01A-11D-2166-01): tumor purity 0.35, ploidy 2.64, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 165 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:52,192,159–54,859,812, 35 genes, copy number 6–8 (within-gene range 4–8): LINC01524, AL109610.1, AL049765.2, AL049765.1, MRPS33P4, AL031674.1, AL161945.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1, AL133335.2, PFDN4, AL133335.1, DOK5, RNU4ATAC7P.
- chr20:62,183,029–64,313,132, 130 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,338. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
